Somatic mutation profile of tumor specimen TCGA-N5-A4RO-01A (aliquot TCGA-N5-A4RO-01A-11D-A28R-08) from TCGA case TCGA-N5-A4RO, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IIIC2; Age at diagnosis: 68.0 years (24,823 days).
Specimen TCGA-N5-A4RO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27c921de-ac85-4f63-b9c2-731d13c95488.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N5-A4RO-10A (Blood Derived Normal), aliquot TCGA-N5-A4RO-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d62a434d-8c65-4796-a7c2-f033ca751191

The open-access MAF lists 55 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 37, Silent 11, Nonsense Mutation 5, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1268G>T p.G423V (on ENST00000281708 / NM_001349798.2; = p.G343V on NM_018315.5) | Missense Mutation (SNP) | VAF 49/114 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157879635, COSV55892390, COSV99657129; called by muse, mutect2, varscan2
- TP53 | c.112del p.Q38Kfs*6 | Frame Shift Del (DEL) | VAF 185/274 reads (68%) | catalogued as rs1555526795, CM107390, COSV52689258; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CACNA1E | c.2813G>A p.R938Q | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs762485881, COSV100706283, COSV62382855; called by muse, mutect2, varscan2
- CYFIP2 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.857); catalogued as COSV59052619; called by muse, mutect2, varscan2
- DST | c.19557G>T p.L6519F (on ENST00000361203 / NM_001374722.1; = p.L4216F on NM_015548.5) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99760555; called by muse, mutect2, varscan2
- DYTN | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 18/31 reads (58%) | catalogued as rs372283021, COSV65970567; called by muse, mutect2, varscan2
- FAM135B | c.2101C>T p.R701* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as rs754073531, COSV52744808; called by muse, mutect2, varscan2
- FSCN3 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as rs755925777, COSV50002450; called by muse, mutect2, varscan2
- H3C7 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV55101191; called by muse, mutect2, varscan2
- KPRP | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 65/106 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs148079077; called by muse, mutect2, varscan2
- MUC17 | c.9010G>T p.A3004S | Missense Mutation (SNP) | VAF 175/667 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.739); catalogued as rs1487382053; called by muse, mutect2, varscan2
- MYO15A | c.8731G>A p.V2911M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs747830108, COSV52760741; called by muse, mutect2, varscan2
- OR4N5 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as rs202234247, COSV61320453; called by muse, mutect2, varscan2
- PCARE | c.3248C>T p.P1083L | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1479806765; called by muse, mutect2, varscan2
- PIK3CA | c.3174C>G p.I1058M | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV56029980; called by muse, mutect2, varscan2
- RGS14 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV104435393; called by muse, mutect2, varscan2
- SETDB1 | c.2795G>A p.R932Q | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs773137921; called by muse, mutect2, varscan2
- SPOP | c.218C>G p.P73R | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100753231, COSV61654230; called by muse, mutect2, varscan2
- THSD7A | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as rs1217195809, COSV70263601; called by muse, mutect2, varscan2
- TIAM1 | c.1058C>G p.T353S | Missense Mutation (SNP) | VAF 101/336 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.22); catalogued as COSV54538511; called by muse, mutect2, varscan2
- C1QBP | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2
- CASZ1 | c.4820G>A p.G1607D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.118); called by muse, mutect2
- CCL11 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); called by muse, mutect2
- CLASP2 | c.3050T>C p.I1017T (on ENST00000359576; = p.I1016T on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- INO80D | c.882C>G p.F294L | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPK6 | c.1818C>G p.F606L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MATN4 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 21/233 reads (9%) | PolyPhen probably damaging (1); called by muse, mutect2
- MC3R | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MGAM | c.5194A>G p.K1732E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MTARC2 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- NDUFB5 | c.213G>A p.L71= | Splice Region (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- OMA1 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- RTL5 | c.834A>T p.K278N | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- SDR9C7 | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SPG7 | c.2003C>T p.S668F (on ENST00000268704; = p.S675F on NM_003119.4) | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TTN | c.17365C>G p.Q5789E (on ENST00000591111; = p.Q4862E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | PolyPhen benign (0.053); called by muse, mutect2, varscan2
- UQCRC1 | c.1208T>A p.L403Q | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VSIG4 | c.1142T>C p.L381P | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- WDR88 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNT9B | c.431C>G p.T144S | Missense Mutation (SNP) | VAF 123/132 reads (93%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ZIC2 | c.617C>A p.S206* | Nonsense Mutation (SNP) | VAF 13/119 reads (11%) | called by muse, varscan2
- ZNF19 | c.793A>G p.R265G | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF585A | c.536C>G p.T179S (on ENST00000292841 / NM_001288800.2; = p.T124S on NM_152655.3) | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF775 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2
- ADAMTSL1 | c.2547T>C p.C849= | Silent (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- CUBN | c.9984C>G p.T3328= | Silent (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- GRIA4 | c.243C>T p.N81= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as rs1407315110, COSV99235446; called by muse, mutect2, varscan2
- KIR2DL3 | c.27G>A p.V9= | Silent (SNP) | VAF 45/222 reads (20%) | called by muse, mutect2, varscan2
- RADX | c.1272G>A p.S424= | Silent (SNP) | VAF 20/25 reads (80%) | catalogued as rs372633270; called by muse, mutect2, varscan2
- RASGRP1 | c.372G>A p.K124= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV100171826; called by muse, mutect2, varscan2
- RORC | c.225C>T p.I75= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs1342121369, COSV100562048; called by muse, mutect2, varscan2
- SUV39H2 | c.561T>C p.A187= (on ENST00000354919 / NM_001193424.2; = p.A127= on NM_024670.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- UBE2L6 | c.24G>T p.V8= | Silent (SNP) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- VSIG4 | c.1143G>T p.L381= | Silent (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- WDR72 | c.828T>C p.G276= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
